Somatic mutation profile of tumor specimen TCGA-39-5031-01A (aliquot TCGA-39-5031-01A-01D-1441-08) from TCGA case TCGA-39-5031, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.0 years (28,106 days).
Specimen TCGA-39-5031-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c402e51-812a-48cb-afcf-f528626068ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5031-11A (Solid Tissue Normal), aliquot TCGA-39-5031-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8700d3b-e8e8-479b-96b8-cd885b5232c6

The open-access MAF lists 669 somatic variants for this specimen: 492 protein-altering or splice-affecting, 160 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 414, Silent 160, Nonsense Mutation 43, Frame Shift Del 17, Intron 13, Splice Site 8, In Frame Del 5, RNA 3, Splice Region 2, Nonstop Mutation 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL2 | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV62929724; called by muse, mutect2
- AAK1 | c.2755G>T p.D919Y | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68642200; called by muse, mutect2, varscan2
- ABCD2 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV58050101; called by muse, mutect2, varscan2
- AC004922.1 | c.636C>A p.F212L | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV53555765, COSV53555833; called by muse, mutect2
- AC020765.6 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1320337410, COSV63456779; called by muse, mutect2, varscan2
- ACAD11 | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs963625210, COSV51442203; called by muse, mutect2, varscan2
- ACMSD | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV51605916; called by muse, mutect2, varscan2
- ACOXL | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs745568724, COSV61322643; called by muse, mutect2, varscan2
- ADAM22 | c.939G>C p.M313I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV55971623; called by muse, mutect2
- ADGRV1 | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67979977; called by muse, mutect2
- AFF2 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.75); catalogued as COSV53979899; called by muse, mutect2, varscan2
- AHNAK | c.4430_4432del p.E1477del | In Frame Del (DEL) | VAF 72/341 reads (21%) | catalogued as rs764571710; called by mutect2, pindel, varscan2
- AHNAK | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 124/521 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV57206001; called by muse, mutect2, varscan2
- AHNAK2 | c.12766G>T p.V4256F | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV60909758, COSV60913985; called by muse, varscan2
- AHNAK2 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 40/481 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.359); catalogued as rs766545042, COSV60909789; called by muse, mutect2
- AHNAK2 | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60909797; called by muse, mutect2, varscan2
- AKAP3 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.304); catalogued as COSV57414658, COSV57420537; called by muse, mutect2, varscan2
- AKAP5 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV57742153; called by muse, mutect2
- ALG13 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV52636102; called by muse, mutect2, varscan2
- ALMS1 | c.11615C>G p.S3872C | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as CD156291, COSV52504525; called by muse, mutect2
- ALPK3 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV51930837; called by muse, mutect2, varscan2
- AMER3 | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264854124, COSV58465494; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7424A>G p.Y2475C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs1312855767, COSV51842220; called by mutect2, varscan2
- ANKLE2 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV61708139, COSV61709002; called by muse, mutect2
- ANKRD16 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51946926; called by muse, mutect2, varscan2
- ANKRD26 | c.782C>A p.S261* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as COSV65793222, COSV65798211; called by muse, mutect2, varscan2
- ANKS6 | c.2123G>C p.G708A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.022); catalogued as COSV62049265; called by muse, mutect2, varscan2
- AOPEP | c.2242C>T p.R748W (on ENST00000375315 / NM_001193329.1; = p.R649W on NM_032823.5) | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953383793, COSV52986513; called by muse, mutect2
- AOX1 | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53495560; called by muse, mutect2, varscan2
- AP1M1 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1453358092, COSV52225219; called by muse, mutect2, varscan2
- AP2A1 | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV58240955, COSV58241025; called by muse, mutect2, varscan2
- APBA1 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as COSV55223055; called by muse, mutect2
- APOL1 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs375964420, COSV59868652; called by muse, mutect2, varscan2
- ARHGAP35 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 40/149 reads (27%) | catalogued as COSV101352024, COSV68329644; called by muse, mutect2, varscan2
- ARHGEF17 | c.5509A>G p.N1837D | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55230339; called by muse, mutect2, varscan2
- ARHGEF26 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377732491; called by muse, mutect2
- ARHGEF39 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58396622; called by muse, mutect2
- ARID5B | c.2606C>G p.S869C | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV54415661; called by muse, mutect2, varscan2
- ARMC8 | c.1984G>A p.D662N (on ENST00000469044 / NM_001363941.2; = p.D648N on NM_015396.6) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV58616971; called by muse, mutect2
- ARR3 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52103378; called by muse, mutect2, varscan2
- ARSL | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV66964925; called by muse, mutect2, varscan2
- ATG4D | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs376428796; called by muse, mutect2
- ATP5F1A | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56359694; called by muse, mutect2
- ATP6V1A | c.1854G>C p.*618Yext*3 | Nonstop Mutation (SNP) | VAF 9/92 reads (10%) | catalogued as COSV56361296, COSV56361378; called by muse, mutect2, varscan2
- B4GALT3 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs769702808, COSV60526643; called by muse, mutect2, varscan2
- BAG6 | c.3370G>A p.E1124K (on ENST00000676571; = p.E1077K on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs1345218709, COSV52988690; called by muse, mutect2
- BCLAF3 | c.2071C>G p.H691D (on ENST00000379682 / NM_001367774.1; = p.H662D on NM_198279.3) | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61413325; called by muse, mutect2, varscan2
- BMP15 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1243842126, COSV53140095; called by muse, mutect2, varscan2
- BMP2K | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55008807; called by muse, mutect2
- BRD4 | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1305915305, COSV54583272; called by muse, mutect2, varscan2
- BRINP1 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56294043; called by muse, mutect2, varscan2
- BRMS1 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV60819796; called by muse, mutect2, varscan2
- BRWD1 | c.6010G>A p.E2004K | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); catalogued as rs201905326, COSV60893173; called by muse, varscan2
- BSN | c.7187G>A p.R2396Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1445466169, COSV56514024; called by muse, mutect2
- C2CD3 | c.2652G>C p.W884C | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100487107, COSV58090396; called by muse, mutect2, varscan2
- C8orf34 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV61373165, COSV61389401; called by muse, mutect2, varscan2
- CACNA1B | c.4686C>G p.I1562M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53117082; called by muse, mutect2
- CACNA1B | c.5702A>C p.Q1901P | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV53117093; called by muse, mutect2, varscan2
- CACNA1G | c.4757C>G p.S1586* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV61721363; called by muse, mutect2, varscan2
- CADM1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs771024754, COSV59004962; called by muse, mutect2, varscan2
- CAGE1 | c.2158G>C p.A720P (on ENST00000512086; = p.A584P on NM_205864.3) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV57075348; called by muse, mutect2, varscan2
- CALB1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV55366802; called by muse, mutect2, varscan2
- CAPN13 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV54428969; called by muse, mutect2, varscan2
- CARMIL1 | c.1156C>A p.L386I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV61514836; called by muse, mutect2, varscan2
- CCDC191 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55670651; called by muse, mutect2, varscan2
- CCDC33 | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV58349033; called by muse, mutect2, varscan2
- CCDC77 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53472136; called by muse, mutect2, varscan2
- CCDC86 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57124612; called by muse, mutect2, varscan2
- CCDC88A | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV55057884; called by muse, mutect2
- CCNE1 | c.181-2A>G p.X61_splice | Splice Site (SNP) | VAF 32/135 reads (24%) | catalogued as COSV52903677; called by muse, mutect2, varscan2
- CCNL1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV55818652; called by muse, mutect2
- CD22 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV50050101; called by muse, mutect2, varscan2
- CDC37 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1294120646, COSV55767540; called by muse, mutect2, varscan2
- CDH10 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.199); catalogued as rs903128657, COSV100050371, COSV52573159; called by muse, mutect2, varscan2
- CDH9 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 130/248 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50256448; called by muse, mutect2, varscan2
- CDKL4 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as rs1398128285, COSV66508672; called by muse, mutect2, varscan2
- CDKL5 | c.1283G>A p.G428D | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV66110482; called by muse, mutect2, varscan2
- CENPB | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60144863; called by muse, mutect2, varscan2
- CERK | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV53450325; called by muse, mutect2, varscan2
- CFAP221 | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV54654542; called by muse, mutect2, varscan2
- CFAP54 | c.8031A>T p.L2677F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.609); catalogued as COSV61571058; called by muse, mutect2
- CHD6 | c.6133C>T p.P2045S | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as COSV64688769; called by muse, mutect2
- CHRDL2 | c.947-1G>A p.X316_splice | Splice Site (SNP) | VAF 12/208 reads (6%) | catalogued as COSV55221882; called by muse, mutect2
- CHSY1 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV54251742; called by muse, mutect2, varscan2
- CIB1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as rs765061684, COSV60172604; called by muse, mutect2, varscan2
- CIP2A | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55417499; called by muse, mutect2, varscan2
- CNST | c.1813G>C p.A605P | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63621537; called by muse, mutect2
- CNTN5 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.058); catalogued as COSV54289113; called by muse, mutect2, varscan2
- COL11A2 | c.4671G>A p.M1557I (on ENST00000341947 / NM_080680.3; = p.M1450I on NM_080679.2) | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59494338; called by muse, mutect2, varscan2
- COX10 | c.354G>C p.L118F | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.251); catalogued as COSV55402842; called by muse, mutect2, varscan2
- COX11 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.934); catalogued as COSV54802555; called by muse, mutect2, varscan2
- CPEB2 | c.2584G>C p.D862H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52589266, COSV52590054; called by muse, mutect2, varscan2
- CPSF3 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53008509; called by muse, mutect2, varscan2
- CPSF4 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 57/427 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV52856695, COSV52858800, COSV99462180; called by muse, varscan2
- CRB1 | c.1805A>T p.D602V | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.698); catalogued as COSV66328984; called by muse, mutect2, varscan2
- CREBBP | c.6943A>T p.S2315C | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV52116383; called by muse, mutect2, varscan2
- CREBBP | c.5300C>T p.S1767L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV52116390; called by muse, mutect2, varscan2
- CRX | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as rs751282380, COSV55756968; called by muse, mutect2, varscan2
- CSE1L | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.364); catalogued as COSV53700599; called by muse, mutect2, varscan2
- CSMD1 | c.4160C>G p.S1387* (on ENST00000520002; = p.S1386* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV59292411; called by muse, mutect2
- CSMD1 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV68176598, COSV68257527; called by muse, mutect2, varscan2
- CST4 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 26/278 reads (9%) | catalogued as COSV54149283; called by muse, varscan2
- CTDSPL2 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as COSV52945077, COSV52947272; called by muse, mutect2
- CTSW | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57171842; called by muse, mutect2
- CTTNBP2NL | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54743417; called by muse, mutect2
- CYP4F2 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV50000463; called by muse, mutect2, varscan2
- DAXX | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455644209, COSV56466568; called by muse, mutect2, varscan2
- DDHD2 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101240780, COSV68157340; called by muse, mutect2
- DDX42 | c.1600C>G p.Q534E | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63789538; called by muse, mutect2, varscan2
- DEFB123 | c.137G>C p.C46S | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383006365, COSV66232964; called by muse, mutect2, varscan2
- DENND1B | c.2240A>G p.H747R | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as COSV54145380; called by muse, mutect2, varscan2
- DISP1 | c.3154T>G p.F1052V | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52655903; called by muse, mutect2, varscan2
- DLGAP2 | c.2938C>A p.P980T | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV70095525; called by muse, mutect2, varscan2
- DNAH10 | c.2609G>C p.G870A (on ENST00000409039; = p.G809A on NM_207437.3) | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV68989339; called by muse, mutect2, varscan2
- DOCK11 | c.3290A>C p.Q1097P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV52234969; called by muse, mutect2, varscan2
- DSC1 | c.2629C>A p.L877I | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57142765; called by muse, mutect2
- EAF2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV56543592; called by muse, mutect2
- EGR1 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1387817209, COSV53518314; called by muse, mutect2
- ELAC2 | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62032062; called by muse, mutect2, varscan2
- EML1 | c.2298C>G p.F766L | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV51742244; called by muse, mutect2, varscan2
- EML4 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as COSV59293945; called by muse, mutect2, varscan2
- ENAM | c.1307C>G p.P436R | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV68535421; called by muse, mutect2, varscan2
- EP400 | c.6106G>A p.D2036N | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV57765244; called by muse, mutect2, varscan2
- ESR2 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV50829088, COSV50829835; called by muse, mutect2
- F13B | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66372676, COSV66375650; called by muse, mutect2, varscan2
- FAM135B | c.3436C>G p.H1146D | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52710543; called by muse, mutect2, varscan2
- FANK1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV64158033, COSV64158637; called by muse, mutect2, varscan2
- FARP1 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 53/397 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV60331813; called by muse, mutect2, varscan2
- FARSA | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs1287519725, COSV53365830; called by muse, mutect2
- FAT2 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | catalogued as COSV55815063; called by muse, mutect2, varscan2
- FBXO15 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54043315; called by muse, mutect2, varscan2
- FLNC | c.5025G>T p.E1675D | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV57951954; called by muse, mutect2, varscan2
- FOS | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771351750, COSV57839117; called by muse, varscan2
- FOXO3 | c.1085G>T p.C362F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV59626721; called by muse, mutect2, varscan2
- FOXP1 | c.1934C>A p.A645D | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59536691; called by muse, mutect2, varscan2
- FRG2C | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1386638927; called by muse, mutect2
- FURIN | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs986796846, COSV51575092; called by muse, mutect2, varscan2
- GABBR1 | c.2529C>G p.F843L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV63541351; called by muse, mutect2, varscan2
- GABPA | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV61395637; called by muse, mutect2
- GALNT11 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57424867; called by muse, mutect2, varscan2
- GART | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV63113601; called by muse, mutect2, varscan2
- GATA1 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100936601, COSV64961726; called by muse, mutect2, varscan2
- GCSAML | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV63577260; called by muse, mutect2, varscan2
- GEMIN4 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as rs1256530299, COSV56745147; called by muse, mutect2, varscan2
- GJD2 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV51747425; called by muse, mutect2
- GK5 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 18/214 reads (8%) | catalogued as COSV101242338, COSV67485402; called by muse, mutect2
- GLYATL1 | c.820C>A p.R274S (on ENST00000317391 / NM_001354699.1; = p.R305S on NM_080661.4) | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV55607610; called by muse, mutect2, varscan2
- GOLGA4 | c.3662G>T p.C1221F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV62709637; called by muse, mutect2, varscan2
- GOLPH3L | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as COSV55045045; called by muse, mutect2, varscan2
- GON4L | c.1843_1845del p.E615del | In Frame Del (DEL) | VAF 20/153 reads (13%) | catalogued as rs767906834; called by pindel, varscan2
- GPATCH2 | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.738); catalogued as COSV65129693; called by muse, mutect2, varscan2
- GPD1L | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV56989336; called by muse, mutect2, varscan2
- GPI | c.1287C>A p.F429L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV62893440, COSV62893659, COSV62894277; called by muse, mutect2, varscan2
- GRAMD1A | c.1892A>G p.Y631C | Missense Mutation (SNP) | VAF 185/451 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58766140; called by muse, mutect2, varscan2
- GREB1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764711785, COSV52182439; called by muse, mutect2, varscan2
- GRIA3 | c.2077-1G>A p.X693_splice | Splice Site (SNP) | VAF 18/163 reads (11%) | catalogued as COSV52051365; called by muse, mutect2, varscan2
- GXYLT2 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67473590; called by muse, mutect2, varscan2
- HCFC1 | c.3277A>T p.T1093S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV60070038; called by muse, mutect2, varscan2
- HEBP2 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV62928133; called by muse, mutect2, varscan2
- HEG1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV60760028; called by muse, mutect2, varscan2
- HELQ | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.005); catalogued as COSV55024394; called by muse, mutect2
- HELZ2 | c.1022_1025del p.N341Ifs*23 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs755605395; called by mutect2, pindel, varscan2
- HEXA | c.912C>G p.F304L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV51505495; called by muse, mutect2, varscan2
- HGS | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs142599461; called by muse, mutect2, varscan2
- HK1 | c.2422G>T p.G808C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53854782; called by muse, mutect2, varscan2
- HOMER3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV55355105; called by muse, mutect2
- HOOK1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs367708992; called by muse, mutect2, varscan2
- HPD | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56641271; called by muse, mutect2, varscan2
- HPS5 | c.3348G>T p.M1116I (on ENST00000349215 / NM_181507.2; = p.M1002I on NM_007216.4) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV61687160; called by muse, mutect2, varscan2
- HRH4 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV56927519; called by muse, mutect2, varscan2
- HSD11B2 | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as rs745899701, COSV52097006; called by muse, mutect2, varscan2
- HSF1 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.342); catalogued as COSV60047113; called by muse, mutect2
- HYDIN | c.10104C>A p.F3368L | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66862633; called by muse, mutect2, varscan2
- ICE1 | c.3882G>C p.M1294I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV56820536; called by muse, mutect2, varscan2
- IFT81 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV54361111; called by muse, mutect2, varscan2
- IGHV3-7 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.608); catalogued as rs370962508; called by muse, mutect2, varscan2
- IGSF21 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52127045, COSV52131426; called by muse, mutect2, varscan2
- ING4 | c.508G>C p.E170Q (on ENST00000396807 / NM_001127582.2; = p.E169Q on NM_016162.4) | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV57523257; called by muse, mutect2, varscan2
- INTS13 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs772898480, COSV53901458; called by mutect2, varscan2
- IPO13 | c.1017G>C p.M339I | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV64893927; called by muse, mutect2
- IQGAP1 | c.3124C>G p.Q1042E | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV51582364; called by muse, mutect2
- ITCH | c.1993A>G p.K665E (on ENST00000262650 / NM_001257137.3; = p.K624E on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52930009; called by muse, mutect2, varscan2
- ITGA6 | c.2815A>G p.K939E (on ENST00000442250; = p.K900E on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV51220195; called by muse, mutect2, varscan2
- ITGA9 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs757641250, COSV53237711; called by muse, mutect2, varscan2
- ITGAM | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54934771; called by muse, mutect2, varscan2
- IVNS1ABP | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62250662; called by muse, mutect2
- IVNS1ABP | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs1275214032, COSV62250664; called by muse, mutect2, varscan2
- JMJD6 | c.813G>C p.W271C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57970556; called by muse, mutect2, varscan2
- JUND | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV53254481; called by muse, mutect2, varscan2
- KAT6A | c.5563A>T p.I1855F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55903804; called by muse, mutect2, varscan2
- KCNH7 | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV59788940; called by muse, mutect2, varscan2
- KCNJ6 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV55710575; called by muse, mutect2, varscan2
- KIAA1210 | c.2858C>A p.P953Q | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV68175936; called by muse, mutect2, varscan2
- KIF4A | c.1206A>T p.L402F | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65541940; called by muse, mutect2, varscan2
- KLHL15 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.219); catalogued as COSV60139446; called by muse, mutect2
- KLHL5 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54672198; called by muse, varscan2
- KMT2D | c.2796A>T p.P932= | Splice Region (SNP) | VAF 36/118 reads (31%) | catalogued as rs757768061, COSV56418517; called by muse, mutect2, varscan2
- KNL1 | c.6689C>T p.S2230L (on ENST00000346991 / NM_170589.5; = p.S2204L on NM_144508.5) | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61152096; called by muse, mutect2
- KNOP1 | c.1278G>A p.W426* | Nonsense Mutation (SNP) | VAF 32/231 reads (14%) | catalogued as COSV54926965; called by muse, mutect2, varscan2
- KRI1 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57263861; called by muse, mutect2, varscan2
- KRT8 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV53176210; called by muse, mutect2, varscan2
- KTN1 | c.2497-1G>T p.X833_splice | Splice Site (SNP) | VAF 18/120 reads (15%) | catalogued as COSV63215509; called by muse, mutect2, varscan2
- L1TD1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV63133204; called by muse, mutect2, varscan2
- LARP1B | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV52793858, COSV52795197; called by muse, mutect2, varscan2
- LBR | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55287832; called by muse, mutect2, varscan2
- LCN8 | c.240G>C p.E80D (on ENST00000612714 / NM_001345934.1; = p.E57D on NM_178469.3) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.266); catalogued as COSV60209478; called by muse, mutect2, varscan2
- LIN28B | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV61493609; called by muse, mutect2, varscan2
- LIPI | c.604+1G>T p.X202_splice | Splice Site (SNP) | VAF 7/144 reads (5%) | catalogued as COSV100753925, COSV60709073; called by muse, mutect2
- LRIG2 | c.2126G>C p.R709P | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.677); catalogued as COSV63161272, COSV63163390; called by muse, mutect2, varscan2
- LRIG2 | c.2952del p.S985Pfs*4 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as COSV63164250; called by mutect2, pindel, varscan2
- LRRC37A | c.4201G>A p.D1401N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV57225363; called by muse, mutect2, varscan2
- LRRC66 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58632424; called by muse, mutect2, varscan2
- LRRTM4 | c.1556C>A p.P519Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.567); catalogued as COSV69153797; called by muse, mutect2, varscan2
- MAD1L1 | c.1509G>T p.L503F | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV56228666; called by muse, varscan2
- MAGI2 | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 73/623 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as rs753778899, COSV62639286, COSV62669584; called by muse, mutect2, varscan2
- MAMLD1 | c.489T>A p.Y163* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as COSV53372708; called by muse, mutect2, varscan2
- MAN1A2 | c.1235C>G p.S412* | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | catalogued as COSV62976698; called by muse, mutect2
- MANBA | c.2590G>C p.D864H (on ENST00000642252; = p.D818H on NM_005908.4) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs755476772, COSV56963452, COSV56964980; called by muse, mutect2
- MAP3K15 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100134886; called by muse, mutect2, varscan2
- MAP7D3 | c.1621A>G p.K541E | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV60170287; called by muse, mutect2, varscan2
- MARCHF10 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV60885704; called by muse, mutect2
- MARCO | c.575C>G p.S192W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV59052524, COSV59056488; called by muse, mutect2, varscan2
- MBD3L1 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV59775786, COSV99977980; called by muse, mutect2, varscan2
- MBOAT7 | c.1285A>C p.I429L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55474689; called by muse, mutect2
- MCM3AP | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs771466046, COSV52437070; called by muse, mutect2, varscan2
- MDC1 | c.4373C>A p.S1458Y | Missense Mutation (SNP) | VAF 31/361 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV64523674, COSV64523819; called by muse, mutect2
- MDN1 | c.13639G>C p.E4547Q | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV65518378; called by muse, mutect2, varscan2
- MDN1 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV65518382; called by muse, mutect2, varscan2
- MELTF | c.1787C>G p.S596* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as rs760761962, COSV56379537; called by muse, mutect2
- MET | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV59257997; called by muse, mutect2
- MIA3 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV60510566; called by muse, mutect2
- MIDN | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758934723, COSV56294380; called by muse, mutect2, varscan2
- MLH3 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53152865; called by muse, mutect2, varscan2
- MME | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.074); catalogued as COSV64706274; called by muse, mutect2, varscan2
- MRAS | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.354); catalogued as COSV56670602; called by muse, mutect2, varscan2
- MRPL55 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as rs745358216, COSV54341954; called by muse, mutect2, varscan2
- MRPS31 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.374); catalogued as COSV60266292, COSV60268579; called by muse, mutect2
- MTMR6 | c.1862G>A p.C621Y | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV67807919; called by muse, mutect2, varscan2
- MTTP | c.396C>G p.V132= | Splice Region (SNP) | VAF 7/57 reads (12%) | catalogued as COSV55504364; called by muse, mutect2, varscan2
- MUC16 | c.17146A>T p.T5716S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1225414520, COSV67451266, COSV67501836; called by muse, mutect2, varscan2
- MUC16 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV67451275; called by muse, mutect2, varscan2
- MXRA5 | c.3886A>T p.M1296L | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs775177515, COSV54226776; called by muse, mutect2, varscan2
- MXRA5 | c.2517A>T p.E839D | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV54226811; called by muse, mutect2, varscan2
- MYF5 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV57354600; called by muse, mutect2, varscan2
- MYH1 | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99876131; called by muse, mutect2, varscan2
- MYH2 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV55433191; called by muse, mutect2, varscan2
- MYO15A | c.5631C>A p.Y1877* | Nonsense Mutation (SNP) | VAF 76/179 reads (42%) | catalogued as COSV52753165; called by muse, mutect2, varscan2
- MYO16 | c.2406G>T p.M802I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51781321; called by muse, mutect2, varscan2
- NAALAD2 | c.894C>A p.Y298* | Nonsense Mutation (SNP) | VAF 44/108 reads (41%) | catalogued as COSV58959467, COSV58965282; called by muse, varscan2
- NAF1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 15/115 reads (13%) | catalogued as COSV56803436; called by muse, mutect2, varscan2
- NBAS | c.5424G>C p.M1808I | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55714824; called by muse, mutect2, varscan2
- NCSTN | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.122); catalogued as COSV54185584; called by muse, mutect2, varscan2
- NECTIN1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.367); catalogued as COSV50598263; called by muse, mutect2, varscan2
- NECTIN3 | c.359G>C p.R120T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100162153, COSV60550212; called by muse, mutect2, varscan2
- NES | c.2694G>A p.W898* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV63960523; called by muse, mutect2, varscan2
- NKX2-2 | c.174C>A p.S58R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65819245; called by muse, mutect2, varscan2
- NLGN4X | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52008121; called by muse, mutect2, varscan2
- NLRP9 | c.2108G>C p.R703T | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV60460623; called by muse, mutect2, varscan2
- NOP2 | c.1997C>T p.S666F (on ENST00000322166 / NM_001258308.2; = p.S662F on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); catalogued as COSV59109749; called by muse, mutect2, varscan2
- NOTCH2 | c.4174C>T p.Q1392* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV56684349; called by muse, mutect2, varscan2
- NR2C2 | c.420C>G p.F140L (on ENST00000393102; = p.F159L on NM_003298.5) | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60145082; called by muse, mutect2, varscan2
- NRDC | c.1325A>T p.Y442F | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61402181; called by muse, mutect2, varscan2
- NRDE2 | c.45T>A p.D15E | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62962399; called by muse, mutect2, varscan2
- NSD3 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV57667555; called by muse, mutect2, varscan2
- NT5DC3 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV67321351; called by muse, mutect2, varscan2
- NUP153 | c.3617C>T p.S1206F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV100020418; called by muse, mutect2, varscan2
- NUP210 | c.4006G>A p.E1336K | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV54403491, COSV99597371; called by muse, varscan2
- NUP98 | c.2495C>T p.T832I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61429542; called by muse, mutect2, varscan2
- OR10R2 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV63768555; called by muse, mutect2, varscan2
- OR11L1 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476193370, COSV63313436, COSV63313826; called by muse, mutect2, varscan2
- OR1F1 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as COSV58960508; called by muse, mutect2, varscan2
- OR2B11 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV59509512; called by muse, mutect2, varscan2
- OR4D1 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as COSV52124666; called by muse, mutect2, varscan2
- OR4D9 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 25/313 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61434242; called by muse, mutect2
- OR5AS1 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57981079; called by muse, mutect2, varscan2
- OR5B3 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV58676555, COSV58676778, COSV58677239; called by muse, mutect2
- OR5H14 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV101454076, COSV71193597; called by muse, mutect2, varscan2
- OR9A4 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs782482254, COSV71885099; called by muse, mutect2
- P3H2 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV100077208, COSV60019189; called by muse, mutect2
- P4HA2 | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 16/180 reads (9%) | catalogued as COSV51324042; called by muse, mutect2
- P4HB | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV58940296; called by muse, mutect2, varscan2
- PARP9 | c.2095G>C p.V699L | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); catalogued as COSV64450137; called by muse, mutect2, varscan2
- PATJ | c.4018C>G p.P1340A | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV56247659; called by muse, mutect2
- PAX2 | c.723G>C p.Q241H (on ENST00000428433 / NM_003987.5; = p.Q218H on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/265 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV62290467, COSV62291112; called by muse, mutect2, varscan2
- PBRM1 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56264876; called by muse, mutect2
- PBX3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.011); catalogued as rs1183498146, COSV60731043; called by muse, mutect2, varscan2
- PCDHA7 | c.1365C>G p.F455L | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV65342440, COSV65343682; called by muse, mutect2, varscan2
- PCLO | c.8670G>T p.Q2890H | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV61621095; called by muse, mutect2, varscan2
- PCNT | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs1291503523, COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2, varscan2
- PCOLCE2 | c.938C>G p.S313* | Nonsense Mutation (SNP) | VAF 23/239 reads (10%) | catalogued as COSV55997931; called by muse, mutect2
- PDE3B | c.2560C>T p.H854Y | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555006627, COSV56380722; called by muse, mutect2, varscan2
- PDGFRB | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.11); catalogued as COSV55802059; called by muse, mutect2, varscan2
- PDP1 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as COSV52600423; called by muse, mutect2, varscan2
- PEX1 | c.1098T>G p.D366E | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV50395238; called by muse, mutect2, varscan2
- PIK3AP1 | c.877A>T p.N293Y | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as COSV59530885, COSV59532913; called by muse, mutect2
- PKD2 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1385712672, CM150950, COSV52937048; called by muse, mutect2, varscan2
- PLVAP | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV53083827; called by muse, mutect2, varscan2
- PLXNA4 | c.3698C>A p.P1233Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.346); catalogued as COSV58110240; called by mutect2, varscan2
- POLA1 | c.2538C>A p.D846E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV66884230; called by muse, mutect2, varscan2
- POLA1 | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66884238; called by muse, mutect2, varscan2
- POLD2 | c.575_576del p.T192Rfs*2 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs751612969; called by pindel, varscan2
- POLG2 | c.814A>C p.N272H | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV73346994; called by muse, mutect2, varscan2
- POLQ | c.4435C>T p.P1479S | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs149344067, COSV51759374; called by muse, mutect2
- POLR3H | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV53441497; called by muse, mutect2, varscan2
- POT1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as COSV62928505; called by muse, varscan2
- PPFIA3 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1184428081, COSV61949585; called by muse, mutect2, varscan2
- PPP1R21 | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 48/210 reads (23%) | catalogued as COSV54282514, COSV54288044; called by muse, mutect2, varscan2
- PPP3CC | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV51499821, COSV51503923; called by muse, mutect2, varscan2
- PPP4R3B | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV55402406, COSV55409407; called by muse, mutect2
- PRADC1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.887); catalogued as rs1464217035, COSV57819977; called by muse, mutect2, varscan2
- PRIM1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV57717079; called by muse, mutect2, varscan2
- PRRG4 | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs1268548994, COSV57672731; called by muse, mutect2
- PRSS23 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs967836388, COSV54706411; called by muse, mutect2, varscan2
- PSMA5 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1312682541, COSV54748157; called by muse, mutect2, varscan2
- PTPN9 | c.1389C>G p.F463L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.052); catalogued as COSV60722851; called by muse, mutect2, varscan2
- PTPN9 | c.1267C>G p.R423G | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.332); catalogued as COSV60722859; called by muse, mutect2, varscan2
- PTPRD | c.4640G>C p.G1547A | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61932561; called by muse, mutect2
- PTPRD | c.3263G>T p.R1088L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV61932572; called by muse, mutect2, varscan2
- QSOX2 | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.607); catalogued as COSV62393574; called by muse, mutect2, varscan2
- RALY | c.648G>T p.K216N (on ENST00000246194 / NM_016732.3; = p.K200N on NM_007367.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV55780165; called by muse, mutect2, varscan2
- RB1 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as CM057980, COSV57295983, COSV57302882; called by muse, mutect2, varscan2
- RBM17 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 22/179 reads (12%) | catalogued as COSV65913681; called by muse, mutect2, varscan2
- RBM46 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV55977503; called by muse, mutect2, varscan2
- RELN | c.8275-1G>C p.X2759_splice | Splice Site (SNP) | VAF 10/118 reads (8%) | catalogued as COSV58989991, COSV59019362; called by muse, mutect2
- RELN | c.4363G>C p.E1455Q | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV58990008; called by muse, mutect2, varscan2
- RELN | c.3911A>C p.K1304T | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV58990020; called by muse, mutect2, varscan2
- REV3L | c.865C>G p.H289D | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1444655392, COSV62616283; called by muse, mutect2, varscan2
- REV3L | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.958); catalogued as COSV100725035, COSV62616293; called by muse, mutect2, varscan2
- RFC4 | c.407C>G p.S136* | Nonsense Mutation (SNP) | VAF 13/254 reads (5%) | catalogued as COSV56215828; called by muse, mutect2
- RGS12 | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV58749491; called by muse, mutect2, varscan2
- RNF220 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59189987; called by muse, mutect2, varscan2
- ROBO1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV71392299; called by muse, mutect2, varscan2
- ROCK1 | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as COSV67694850; called by muse, mutect2
- RPRD2 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 52/166 reads (31%) | catalogued as COSV64818949; called by muse, mutect2, varscan2
- RPS6KB1 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.1); catalogued as COSV56675725; called by muse, mutect2, varscan2
- RTL4 | c.66T>A p.N22K | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV61205751; called by muse, mutect2, varscan2
- RTL8A | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs933205799, COSV66188306; called by muse, mutect2
- RUNX1T1 | c.1515C>G p.I505M (on ENST00000265814 / NM_001198628.1; = p.I478M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV56140042; called by muse, mutect2, varscan2
- S100A13 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59884430; called by muse, mutect2, varscan2
- SBNO1 | c.1349C>G p.S450* (on ENST00000420886; = p.S449* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 19/161 reads (12%) | catalogued as COSV57339521; called by muse, mutect2, varscan2
- SCAF11 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV65474614, COSV65475368; called by muse, mutect2, varscan2
- SCARB2 | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV53667905; called by muse, mutect2, varscan2
- SDE2 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV55250236; called by muse, mutect2, varscan2
- SEC14L5 | c.1331G>T p.R444M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52036981; called by muse, mutect2, varscan2
- SEL1L | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 19/172 reads (11%) | catalogued as COSV60919463; called by muse, mutect2, varscan2
- SEMA3G | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.79); catalogued as COSV51594199, COSV51595815; called by muse, mutect2
- SERPINB12 | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 91/391 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54032358; called by muse, mutect2, varscan2
- SERPINB5 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV66975073; called by muse, mutect2, varscan2
- SERPIND1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142451096, CM043091; called by muse, mutect2, varscan2
- SFSWAP | c.2124G>C p.E708D | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55520260; called by muse, mutect2, varscan2
- SGO2 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV63414238; called by muse, mutect2, varscan2
- SH3TC1 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV55282052; called by muse, mutect2
- SHPK | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs770810902, COSV50439917; called by mutect2, varscan2
- SHROOM2 | c.4038G>C p.L1346F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66605163; called by muse, mutect2, varscan2
- SHROOM3 | c.3078G>A p.M1026I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV56024748; called by muse, mutect2, varscan2
- SIPA1L3 | c.4903G>T p.D1635Y | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780501745, COSV55910080; called by muse, mutect2, varscan2
- SKA1 | c.662C>G p.T221S | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1254669645, COSV53278325; called by muse, mutect2, varscan2
- SLC12A7 | c.1869G>C p.M623I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV53755129; called by muse, mutect2, varscan2
- SLC16A11 | c.1152G>A p.M384I (on ENST00000308009; = p.M360I on NM_153357.3) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV57273867; called by muse, mutect2, varscan2
- SLC18A3 | c.1393G>T p.V465F | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV60321325; called by muse, mutect2, varscan2
- SLC24A3 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as COSV60114000; called by muse, mutect2
- SLC25A51 | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV54252373; called by muse, mutect2
- SLC26A5 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.368); catalogued as COSV59698327; called by muse, mutect2, varscan2
- SLC2A14 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533714, COSV61585738; called by muse, mutect2, varscan2
- SLC35D1 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52430023, COSV52431350; called by muse, mutect2
- SLC39A6 | c.1956G>A p.M652I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52368138; called by muse, mutect2
- SLC39A6 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as rs1284495918, COSV52368148; called by muse, mutect2, varscan2
- SLC43A3 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as rs151251549; called by muse, mutect2
- SLC45A1 | c.2035C>G p.L679V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV57093496; called by muse, mutect2, varscan2
- SLITRK3 | c.2173C>G p.P725A | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53846238; called by muse, mutect2, varscan2
- SLURP1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as rs750175473, COSV55815924; called by muse, mutect2
- SLX4 | c.5101G>C p.E1701Q | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV53561532; called by muse, mutect2
- SMARCC2 | c.3022G>A p.G1008S | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.039); catalogued as COSV53237583; called by muse, mutect2
- SMC2 | c.2533G>C p.E845Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV53955897; called by muse, mutect2, varscan2
- SNCAIP | c.1609G>C p.V537L | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV54404240; called by muse, mutect2, varscan2
- SNRPD1 | c.15-1G>A p.X5_splice | Splice Site (SNP) | VAF 4/72 reads (6%) | catalogued as COSV55932396; called by muse, mutect2
- SNX15 | c.654C>G p.F218L | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV57246103, COSV57246711; called by muse, mutect2
- SORT1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1231742745, COSV56664813; called by muse, mutect2, varscan2
- SPECC1 | c.1288C>G p.R430G | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV54953954; called by muse, mutect2, varscan2
- SPEF1 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65726887; called by muse, varscan2
- SRRM1 | c.1775C>G p.S592C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV60475691; called by muse, mutect2, varscan2
- ST6GAL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 108/782 reads (14%) | PolyPhen possibly damaging (0.714); catalogued as COSV51467125; called by muse, mutect2, varscan2
- STAB2 | c.5878C>A p.Q1960K | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.146); catalogued as COSV66335590; called by muse, mutect2, varscan2
- SUCO | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV55262918, COSV55268664; called by muse, mutect2, varscan2
- SUFU | c.598-1G>C p.X200_splice | Splice Site (SNP) | VAF 19/99 reads (19%) | catalogued as COSV64014177; called by muse, mutect2, varscan2
- SUSD1 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62582532; called by muse, mutect2
- SUSD5 | c.1058A>T p.K353M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV58876203; called by muse, mutect2, varscan2
- SV2C | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59215689; called by muse, mutect2, varscan2
- SVOPL | c.692C>T p.S231F (on ENST00000419765; = p.S79F on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs868320054, COSV55989048; called by muse, mutect2
- SYNE2 | c.10666G>C p.E3556Q | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100648162, COSV59942159; called by muse, mutect2
- SYNJ1 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1416589801, COSV59145415; called by muse, mutect2, varscan2
- TAF1B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55154561; called by muse, varscan2
- TAF1B | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as COSV55154570, COSV99722109; called by muse, varscan2
- TAF1L | c.4740G>T p.K1580N | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV54259049; called by muse, mutect2, varscan2
- TAF2 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV65417069; called by muse, mutect2, varscan2
- TARBP1 | c.2344C>G p.L782V | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV50178793; called by muse, mutect2, varscan2
- TBC1D31 | c.1488T>A p.Y496* | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | catalogued as COSV54864314; called by muse, mutect2
- TBC1D31 | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54864323; called by muse, mutect2
- TBX18 | c.1491G>T p.Q497H | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.962); catalogued as COSV63736270; called by muse, mutect2, varscan2
- TBXT | c.401C>G p.A134G | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV51616681, COSV51620393; called by muse, mutect2, varscan2
- TCEANC | c.530G>A p.C177Y (on ENST00000380600 / NM_001297563.2; = p.C207Y on NM_152634.4) | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59039410; called by muse, mutect2, varscan2
- TCTN3 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as COSV56445894; called by muse, mutect2, varscan2
- TEKT5 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 39/290 reads (13%) | catalogued as COSV51587064; called by muse, mutect2, varscan2
- THBS2 | c.3042C>G p.F1014L | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV64677409; called by muse, mutect2
- THBS2 | c.2280C>G p.F760L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.303); catalogued as COSV64677413; called by muse, mutect2
- TMC5 | c.2585C>T p.S862L (on ENST00000396229 / NM_001105248.1; = p.S616L on NM_024780.5) | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54901122, COSV54901608; called by muse, mutect2, varscan2
- TMCC1 | c.1378G>C p.D460H (on ENST00000393238 / NM_001349268.2; = p.D136H on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV61439043, COSV61441503; called by muse, mutect2
- TMF1 | c.2774C>A p.S925Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV68373690; called by muse, mutect2, varscan2
- TMPO | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54122355; called by muse, mutect2, varscan2
- TNKS | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV60053095, COSV60054821; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2438C>G p.S813C | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64100244; called by muse, mutect2, varscan2
- TNPO3 | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55278672; called by muse, mutect2, varscan2
- TNRC18 | c.6802G>T p.D2268Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60306570, COSV60308261; called by muse, mutect2
- TOGARAM1 | c.3845G>C p.R1282T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63890890; called by muse, mutect2, varscan2
- TONSL | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV68047813; called by muse, mutect2, varscan2
- TOP2A | c.3350C>G p.S1117C | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV70732206, COSV70733846; called by muse, mutect2, varscan2
- TP53 | c.309C>A p.Y103* | Nonsense Mutation (SNP) | VAF 59/118 reads (50%) | catalogued as CM073388, COSV52663474, COSV52761478, COSV52776039, COSV53023378; called by muse, mutect2, varscan2
- TP63 | c.1227G>C p.E409D | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV53199166, COSV53207930, COSV99286891; called by muse, mutect2
- TRIM45 | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56712783; called by muse, mutect2, varscan2
- TRIM58 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV63569360, COSV63572430; called by muse, mutect2, varscan2
- TRIO | c.7463C>G p.S2488C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); catalogued as rs748080841, COSV59989206; called by muse, mutect2
- TRPV4 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV55680788; called by muse, mutect2, varscan2
- TSHZ3 | c.2885G>A p.G962E | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53666257; called by muse, mutect2, varscan2
- TSHZ3 | c.2654C>A p.S885* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV53666274; called by muse, mutect2, varscan2
- TTN | c.20192G>T p.R6731L (on ENST00000591111; = p.R5804L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | PolyPhen possibly damaging (0.806); catalogued as rs148072021, COSV59923807, COSV59975784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT4 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV57110891; called by muse, mutect2, varscan2
- UCP3 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.104); catalogued as COSV58367689; called by muse, mutect2, varscan2
- UHMK1 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.224); catalogued as rs771235302, COSV56419466; called by muse, mutect2, varscan2
- UNC5A | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56165979, COSV56171899; called by muse, mutect2, varscan2
- UNC79 | c.6615G>C p.L2205F (on ENST00000393151 / NM_001346218.2; = p.L2028F on NM_020818.5) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.515); catalogued as COSV56377841; called by muse, mutect2, varscan2
- UPF1 | c.1186G>C p.D396H (on ENST00000599848 / NM_001297549.2; = p.D385H on NM_002911.4) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV53194350; called by muse, mutect2
- UPP1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774536059, COSV57977175; called by muse, mutect2
- USH2A | c.14413G>A p.V4805I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs147532612; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- USH2A | c.3554C>A p.S1185Y | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56337399, COSV56364078; called by muse, mutect2, varscan2
- USP29 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV54140698, COSV54144567; called by muse, mutect2, varscan2
- USP34 | c.2876A>G p.D959G | Missense Mutation (SNP) | VAF 150/233 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV68399268; called by muse, mutect2, varscan2
- VCPIP1 | c.3042G>C p.K1014N | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV60046224; called by muse, mutect2, varscan2
- VGLL2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58309053; called by muse, mutect2, varscan2
- VIL1 | c.2014_2016del p.K672del | In Frame Del (DEL) | VAF 24/168 reads (14%) | catalogued as rs767458059; called by pindel, varscan2
- VPS13B | c.1744C>G p.L582V | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.184); catalogued as COSV62016918; called by muse, mutect2, varscan2
- VPS13D | c.2597C>T p.S866L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV50625384; called by muse, mutect2, varscan2
- WBP11 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as COSV53762069; called by muse, mutect2, varscan2
- WDR59 | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV50933676; called by muse, mutect2, varscan2
- WNK3 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63612444; called by muse, mutect2, varscan2
- XPOT | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV60344280; called by muse, mutect2, varscan2
- XPOT | c.2526G>C p.Q842H | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV60344286; called by muse, mutect2, varscan2
- ZCCHC2 | c.3073G>T p.G1025* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV54036575; called by muse, mutect2, varscan2
- ZEB2 | c.2240T>A p.L747H | Missense Mutation (SNP) | VAF 138/330 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV57952698; called by muse, mutect2, varscan2
- ZFP36L1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60544617; called by muse, mutect2, varscan2
- ZMYM3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.055); catalogued as COSV58736556; called by muse, mutect2, varscan2
- ZMYM6 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV58183803; called by muse, mutect2, varscan2
- ZNF274 | c.952G>T p.E318* (on ENST00000610905; = p.E213* on NM_016324.3) | Nonsense Mutation (SNP) | VAF 38/171 reads (22%) | catalogued as COSV58763370; called by muse, mutect2, varscan2
- ZNF318 | c.6172G>T p.D2058Y | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV58930775; called by muse, mutect2, varscan2
- ZNF441 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 15/158 reads (9%) | catalogued as COSV63539234; called by muse, mutect2
- ZNF442 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV54420703, COSV54422260; called by muse, mutect2
- ZNF468 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV54693635; called by muse, mutect2, varscan2
- ZNF507 | c.840C>G p.I280M | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV61330320; called by muse, mutect2
- ZNF530 | c.1781G>T p.R594I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV60531025; called by muse, mutect2
- ZNF554 | c.1533G>C p.Q511H | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV57884661; called by muse, mutect2, varscan2
- ZNF586 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV66972165; called by muse, varscan2
- ZNF606 | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV58705291; called by muse, mutect2, varscan2
- ZNF668 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.422); catalogued as COSV100336235, COSV56212110; called by muse, mutect2, varscan2
- ZNF708 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100803117; called by muse, mutect2
- ZNF708 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63606955; called by muse, mutect2
- ZNF711 | c.1230G>C p.M410I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52151993; called by muse, mutect2, varscan2
- ZNF711 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV52152008; called by muse, mutect2, varscan2
- ZNF85 | c.260G>C p.W87S | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100059792, COSV56021156; called by muse, mutect2
- ZNF99 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV68055034; called by muse, mutect2, varscan2
- ZNFX1 | c.3752G>C p.R1251P | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65594886, COSV65596116; called by muse, mutect2, varscan2
- ZSCAN31 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 12/304 reads (4%) | catalogued as COSV60180375; called by muse, mutect2
- ZXDC | c.1750C>T p.L584F | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.448); catalogued as rs1172707225, COSV60445958; called by muse, mutect2
- ATP8B1 | c.1376_1377del p.L459Hfs*8 | Frame Shift Del (DEL) | VAF 62/330 reads (19%) | called by mutect2, pindel, varscan2
- CES1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.015); called by muse, mutect2
- CIP2A | c.297_300del p.N100Vfs*27 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- COIL | c.1547del p.S516Yfs*6 | Frame Shift Del (DEL) | VAF 28/290 reads (10%) | called by pindel, varscan2
- DMXL2 | c.7799del p.P2600Hfs*63 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- GTF2F2 | c.543_545del p.Q181del | In Frame Del (DEL) | VAF 42/150 reads (28%) | called by pindel, varscan2
- HDLBP | c.2875_2876del p.K959Vfs*2 | Frame Shift Del (DEL) | VAF 47/126 reads (37%) | called by mutect2, pindel, varscan2
- IGHG4 | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT5 | c.1632_1645del p.S547Wfs*20 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- MIPOL1 | c.1122_1123del p.N375Hfs*10 | Frame Shift Del (DEL) | VAF 30/174 reads (17%) | called by pindel, varscan2
- MYO7B | c.2699del p.K900Rfs*26 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- NRXN3 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCSK5 | c.4125_4128del p.C1375Wfs*51 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- PRR14 | c.967del p.L323Sfs*135 | Frame Shift Del (DEL) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- SEMA4F | c.885_887del p.L296del | In Frame Del (DEL) | VAF 30/236 reads (13%) | called by mutect2, pindel, varscan2
- SLC26A3 | c.413del p.G138Dfs*2 | Frame Shift Del (DEL) | VAF 39/179 reads (22%) | called by mutect2, pindel, varscan2
- SOS1 | c.3220_3221del p.E1074Kfs*32 | Frame Shift Del (DEL) | VAF 70/214 reads (33%) | called by mutect2, pindel, varscan2
- TMEM140 | c.529_530del p.R177Gfs*2 | Frame Shift Del (DEL) | VAF 14/150 reads (9%) | called by pindel, varscan2
- TRBV4-1 | c.95T>C p.M32T | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UBE3A | c.313_320dup p.C108Tfs*7 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | called by mutect2, varscan2
- ZNF567 | c.1854_1857del p.C619Mfs*30 (on ENST00000536254 / NM_001322913.1; = p.C588Mfs*30 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- ABCA7 | c.2470C>T p.L824= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV54025267; called by muse, varscan2
- ABRA | c.342C>T p.V114= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as COSV61732014; called by muse, mutect2
- ACE | c.819C>T p.L273= | Silent (SNP) | VAF 17/184 reads (9%) | catalogued as rs148882466, COSV52004296; called by muse, mutect2
- ACOT4 | c.837G>A p.L279= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV58335426; called by muse, mutect2
- ACTA1 | c.933C>T p.I311= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV64202990; called by muse, mutect2, varscan2
- ADGRV1 | c.6456G>A p.V2152= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV67979981; called by muse, mutect2
- AHNAK2 | c.4716C>G p.L1572= | Silent (SNP) | VAF 46/460 reads (10%) | catalogued as rs1386236727, COSV60909783; called by muse, mutect2
- ATP1A3 | c.624C>A p.I208= (on ENST00000545399 / NM_001256214.2; = p.I195= on NM_152296.5) | Silent (SNP) | VAF 43/220 reads (20%) | catalogued as COSV57485841; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1146C>T p.I382= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as rs547299743, COSV57747990; called by muse, mutect2, varscan2
- BTNL2 | c.54C>T p.F18= | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as COSV66630357; called by muse, mutect2, varscan2
- C2CD2L | c.2091C>G p.P697= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV60883752; called by muse, varscan2
- CAMTA1 | c.3054G>C p.G1018= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV57885994; called by muse, mutect2, varscan2
- CASK | c.885G>A p.L295= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as COSV59363088; called by muse, mutect2, varscan2
- CATIP | c.1050C>T p.F350= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV56822314; called by muse, mutect2, varscan2
- CCDC141 | c.2703C>A p.A901= | Silent (SNP) | VAF 196/439 reads (45%) | catalogued as COSV55370350, COSV55384748; called by muse, mutect2, varscan2
- CCDC62 | c.267C>G p.L89= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV53431186; called by muse, mutect2, varscan2
- CCDC66 | c.972G>C p.V324= (on ENST00000394672 / NM_001353147.1; = p.V290= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 39/193 reads (20%) | catalogued as COSV58301817; called by muse, mutect2, varscan2
- CD1A | c.873C>T p.V291= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV56860713, COSV99192571; called by muse, mutect2, varscan2
- CELSR3 | c.7761C>T p.L2587= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV50841532; called by muse, mutect2, varscan2
- CFAP52 | c.297G>A p.K99= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs1260002210, COSV55343399; called by muse, mutect2, varscan2
- CNOT9 | c.579C>T p.D193= | Silent (SNP) | VAF 81/239 reads (34%) | catalogued as COSV55299309; called by muse, mutect2, varscan2
- COG2 | c.135G>A p.L45= | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as COSV64186126; called by muse, mutect2
- COL11A1 | c.3882T>A p.G1294= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV62175411; called by muse, mutect2, varscan2
- COL5A1 | c.1638G>A p.A546= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs775508023, COSV65666262; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPT1A | c.537C>G p.V179= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV55753711; called by muse, mutect2
- CRX | c.856C>T p.L286= | Silent (SNP) | VAF 69/328 reads (21%) | catalogued as COSV55757328; called by muse, mutect2, varscan2
- CSMD3 | c.3447C>A p.L1149= (on ENST00000297405 / NM_001363185.1; = p.L1045= on NM_052900.3) | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV52122270; called by muse, mutect2, varscan2
- DGKB | c.408G>A p.K136= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV51767363, COSV99335422; called by muse, mutect2
- DIAPH1 | c.2199C>T p.P733= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs368848606; called by muse, mutect2
- DIP2A | c.1974G>C p.L658= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV59473800; called by muse, mutect2, varscan2
- DLG4 | c.1884C>T p.L628= (on ENST00000399506 / NM_001321075.3; = p.L671= on NM_001365.4) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs574653579, COSV57237052; called by muse, mutect2, varscan2
- DPEP2 | c.462C>T p.D154= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV52054029; called by muse, mutect2
- DSP | c.1566C>T p.L522= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs765994390, COSV65791601; called by muse, mutect2, varscan2
- DUS3L | c.1914C>T p.F638= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs780175670, COSV57831326; called by muse, mutect2, varscan2
- EDC4 | c.3267C>G p.L1089= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1449723424, COSV59302099; called by muse, mutect2, varscan2
- ELK1 | c.1146G>A p.L382= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV55952189; called by muse, mutect2, varscan2
- EMC2 | c.165A>T p.I55= | Silent (SNP) | VAF 108/263 reads (41%) | catalogued as COSV55208304; called by muse, mutect2, varscan2
- EPHA8 | c.171C>T p.I57= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as COSV51263964; called by muse, mutect2, varscan2
- EZH2 | c.943C>T p.L315= (on ENST00000460911 / NM_001203247.2; = p.L320= on NM_004456.5) | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs6954744, COSV57448308, COSV57450341; called by muse, mutect2, varscan2
- FBXO10 | c.558A>T p.P186= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV52831761; called by muse, mutect2, varscan2
- FERMT3 | c.1038C>A p.L346= | Silent (SNP) | VAF 30/326 reads (9%) | catalogued as COSV54177603, COSV99656251; called by muse, mutect2
- FHIT | c.51C>G p.L17= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV59287371; called by muse, mutect2, varscan2
- FLT1 | c.201G>A p.V67= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV56720548; called by muse, mutect2, varscan2
- GLYR1 | c.1053C>T p.I351= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1169418408, COSV58925966; called by muse, mutect2, varscan2
- GPN3 | c.537G>C p.L179= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV57401270; called by muse, mutect2
- GPRASP1 | c.114C>A p.P38= | Silent (SNP) | VAF 40/292 reads (14%) | catalogued as COSV64354988; called by muse, varscan2
- H1-5 | c.138G>C p.L46= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as COSV58899291; called by muse, mutect2, varscan2
- H2BC18 | c.105G>A p.K35= | Silent (SNP) | VAF 123/397 reads (31%) | catalogued as COSV58943866; called by muse, mutect2, varscan2
- HCN1 | c.1371G>A p.L457= | Silent (SNP) | VAF 15/201 reads (7%) | catalogued as COSV57491077, COSV57497442, COSV57503513; called by muse, mutect2
- HIF3A | c.435G>C p.L145= (on ENST00000377670 / NM_152795.4; = p.L76= on NM_022462.4) | Silent (SNP) | VAF 24/190 reads (13%) | catalogued as COSV52196342; called by muse, mutect2, varscan2
- HTR3C | c.1278C>T p.L426= | Silent (SNP) | VAF 24/630 reads (4%) | catalogued as COSV59174507; called by muse, mutect2
- IL1RAPL1 | c.1054C>A p.R352= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV56243443; called by muse, mutect2, varscan2
- ITGA2 | c.2919C>T p.F973= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs1200159418, COSV56857196; called by muse, mutect2, varscan2
- ITGA9 | c.324G>T p.R108= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV53237722; called by muse, mutect2, varscan2
- ITIH2 | c.735G>A p.Q245= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV64432278, COSV64432583; called by muse, mutect2, varscan2
- JCAD | c.723G>A p.L241= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as COSV100948425, COSV64758361; called by muse, mutect2, varscan2
- JMJD6 | c.912G>T p.G304= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV58300670; called by muse, mutect2, varscan2
- KCTD8 | c.744C>T p.F248= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs911454417, COSV63586187; called by muse, mutect2, varscan2
- KDM3A | c.3933G>A p.L1311= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV57218975; called by muse, mutect2, varscan2
- KIR2DL1 | c.321C>T p.S107= | Silent (SNP) | VAF 134/1196 reads (11%) | catalogued as rs777904843; called by muse, mutect2, varscan2
- KLHL40 | c.1587G>T p.V529= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV55133090; called by muse, mutect2
- KRT37 | c.969G>A p.L323= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV56657129; called by muse, mutect2, varscan2
- KRT37 | c.906C>T p.I302= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as COSV56657148; called by muse, mutect2, varscan2
- KRT37 | c.747G>A p.L249= | Silent (SNP) | VAF 31/256 reads (12%) | catalogued as COSV56657157; called by muse, mutect2, varscan2
- LAMB3 | c.2785C>T p.L929= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV50520474; called by muse, mutect2, varscan2
- LCP2 | c.414C>A p.P138= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs769576361, COSV50447395; called by muse, mutect2, varscan2
- LDLRAD4 | c.288C>T p.F96= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV63334594; called by muse, mutect2, varscan2
- LYSMD3 | c.285C>T p.L95= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV60056664; called by muse, mutect2, varscan2
- MAP3K11 | c.789G>A p.L263= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV58418626; called by muse, mutect2, varscan2
- MAP4K2 | c.2145C>T p.I715= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV53641086; called by muse, mutect2
- MAPK1 | c.471C>A p.L157= | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as COSV53185327, COSV53185355; called by muse, mutect2, varscan2
- MCM2 | c.1320A>G p.L440= | Silent (SNP) | VAF 72/263 reads (27%) | catalogued as COSV54032349; called by muse, mutect2, varscan2
- MDC1 | c.3411C>G p.V1137= | Silent (SNP) | VAF 41/336 reads (12%) | catalogued as COSV64523681, COSV64527155; called by muse, mutect2, varscan2
- MIS18BP1 | c.1179C>T p.I393= | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as COSV60369484; called by muse, mutect2
- MISP | c.531G>T p.R177= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53119139; called by muse, mutect2, varscan2
- MKI67 | c.6303A>T p.I2101= | Silent (SNP) | VAF 261/555 reads (47%) | catalogued as COSV64073081; called by muse, mutect2, varscan2
- MLH3 | c.3276G>A p.E1092= | Silent (SNP) | VAF 11/194 reads (6%) | catalogued as COSV53152799; called by muse, mutect2
- MRPS15 | c.468G>A p.L156= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs1024863358, COSV64152183; called by muse, mutect2, varscan2
- MRRF | c.507G>C p.L169= | Silent (SNP) | VAF 23/238 reads (10%) | catalogued as COSV52913401; called by muse, mutect2
- MSH6 | c.1011G>A p.L337= | Silent (SNP) | VAF 83/437 reads (19%) | catalogued as COSV52275702; called by muse, mutect2, varscan2
- MXRA5 | c.3105A>G p.Q1035= | Silent (SNP) | VAF 50/230 reads (22%) | catalogued as COSV54226794; called by muse, mutect2, varscan2
- NBEA | c.3060C>T p.V1020= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV59765727; called by muse, mutect2, varscan2
- NETO1 | c.1059G>A p.V353= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV55002771, COSV55006745; called by muse, mutect2
- NFATC1 | c.2232C>T p.L744= | Silent (SNP) | VAF 30/438 reads (7%) | catalogued as rs954133868, COSV53696365; called by muse, mutect2
- NIBAN3 | c.357C>T p.F119= | Silent (SNP) | VAF 19/198 reads (10%) | catalogued as COSV56306076; called by muse, mutect2, varscan2
- NIBAN3 | c.1392C>T p.L464= | Silent (SNP) | VAF 32/275 reads (12%) | catalogued as rs756733224, COSV56306085; called by muse, mutect2, varscan2
- NPHP4 | c.1225C>T p.L409= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV65393728; called by muse, mutect2, varscan2
- NPY1R | c.540T>G p.T180= | Silent (SNP) | VAF 67/144 reads (47%) | catalogued as rs781606902, COSV56713660; called by muse, mutect2, varscan2
- NQO1 | c.414C>T p.F138= | Silent (SNP) | VAF 43/326 reads (13%) | catalogued as COSV57731121; called by muse, mutect2, varscan2
- NRXN3 | c.387C>A p.G129= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1274664213; called by muse, mutect2
- NUDT13 | c.174G>A p.L58= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV61968242; called by muse, mutect2, varscan2
- OBSCN | c.924C>G p.L308= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV52749349; called by muse, mutect2
- OLA1 | c.717G>A p.K239= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV52967909; called by muse, mutect2, varscan2
- OPHN1 | c.1566C>T p.S522= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV62780834; called by muse, mutect2, varscan2
- OR52B2 | c.924G>T p.R308= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs760125194, COSV73209254; called by muse, mutect2, varscan2
- OR5F1 | c.324G>A p.A108= | Silent (SNP) | VAF 22/215 reads (10%) | catalogued as rs1339924868, COSV53545594; called by muse, mutect2, varscan2
- OSMR | c.2283G>A p.L761= | Silent (SNP) | VAF 22/289 reads (8%) | catalogued as COSV57081952, COSV57085295; called by muse, mutect2
- P2RY12 | c.162G>C p.R54= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs781350611, COSV56371425; called by muse, mutect2, varscan2
- PAN2 | c.660G>A p.L220= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV57753026; called by muse, mutect2, varscan2
- PARP14 | c.384C>G p.L128= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs1055302985, COSV71734231, COSV71735408; called by muse, mutect2, varscan2
- PAX1 | c.891C>A p.G297= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV68271274; called by muse, mutect2, varscan2
- PDGFRA | c.3264C>T p.F1088= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as COSV57265624; called by muse, mutect2
- PIK3C2G | c.2469C>T p.S823= (on ENST00000676171; = p.S782= on NM_004570.5) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56800250; called by muse, mutect2, varscan2
- PIK3CB | c.1104C>T p.I368= | Silent (SNP) | VAF 36/370 reads (10%) | catalogued as rs1354611947, COSV56683995; called by muse, mutect2
- PLEK | c.351C>G p.S117= | Silent (SNP) | VAF 98/342 reads (29%) | catalogued as COSV52250874, COSV52253432, COSV52254522; called by muse, mutect2, varscan2
- PLPP1 | c.591C>G p.L197= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV53303921; called by muse, mutect2, varscan2
- PMS2 | c.99G>A p.L33= | Silent (SNP) | VAF 48/471 reads (10%) | catalogued as rs1562701736, COSV56150072, COSV99764192; ClinVar: likely benign; called by muse, mutect2, varscan2
- POGK | c.810C>G p.V270= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV63311334; called by muse, mutect2, varscan2
- PRDM10 | c.1467G>A p.E489= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as COSV58799758, COSV58804296; called by muse, varscan2
- PRKD2 | c.1365C>T p.F455= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV52184973; called by muse, mutect2
- PRSS1 | c.498G>A p.L166= | Silent (SNP) | VAF 29/439 reads (7%) | catalogued as COSV61190270, COSV61191227; called by muse, mutect2
- PTH | c.180G>A p.Q60= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV56378250; called by muse, mutect2, varscan2
- RHBDF2 | c.825G>A p.P275= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as rs1003036329, COSV57419723; called by muse, mutect2, varscan2
- RIN2 | c.660C>G p.L220= (on ENST00000255006 / NM_001242581.1; = p.L171= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as COSV54785007; called by muse, mutect2
- RING1 | c.795G>C p.V265= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV63002331; called by muse, mutect2
- RIPOR3 | c.2310G>A p.Q770= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as rs377612084; called by muse, mutect2, varscan2
- RNF121 | c.855C>T p.F285= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV52620088; called by muse, mutect2
- RNF43 | c.726G>A p.Q242= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs779091543, COSV68457255; called by muse, mutect2, varscan2
- SCARA3 | c.603C>T p.G201= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV57269562; called by muse, mutect2, varscan2
- SEMA3B | c.801G>A p.Q267= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV60350999; called by muse, mutect2, varscan2
- SF1 | c.87G>A p.Q29= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV57112050; called by muse, mutect2
- SF3B3 | c.1303C>T p.L435= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as COSV56785794; called by muse, mutect2, varscan2
- SH3BP5L | c.945G>T p.G315= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV63538843; called by muse, mutect2
- SLTM | c.1017G>A p.K339= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV51053407; called by muse, mutect2, varscan2
- SMCR8 | c.2262C>T p.V754= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as COSV58175505; called by muse, mutect2, varscan2
- SMG1 | c.10488G>A p.L3496= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as COSV101246157; called by muse, mutect2, varscan2
- SPIDR | c.2682G>A p.P894= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as COSV52371732; called by muse, mutect2, varscan2
- SPTB | c.4449C>T p.I1483= | Silent (SNP) | VAF 37/288 reads (13%) | catalogued as rs199822834; called by muse, mutect2, varscan2
- SRPRB | c.246C>T p.V82= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV71749028, COSV71749144; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1074G>A p.G358= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV50073659; called by muse, mutect2, varscan2
- STAT2 | c.2451G>A p.P817= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs372474228; ClinVar: likely benign; called by muse, mutect2, varscan2
- STMN3 | c.168C>T p.V56= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as COSV64246682; called by muse, mutect2, varscan2
- SYNE2 | c.2925C>T p.L975= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs768605641, COSV59942154; called by muse, mutect2, varscan2
- TBC1D10C | c.87C>T p.S29= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1167480670, COSV56702080; called by muse, mutect2
- TCF7L1 | c.295C>A p.R99= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV56396815; called by muse, mutect2, varscan2
- TEX10 | c.1707C>G p.L569= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs145080863; called by muse, mutect2, varscan2
- TLE4 | c.1029G>A p.L343= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV54627676, COSV99511780; called by muse, mutect2, varscan2
- TMEM86A | c.459T>G p.L153= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV55010220; called by muse, mutect2, varscan2
- TOP1MT | c.627G>A p.L209= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV61316661; called by muse, mutect2, varscan2
- TOPORS | c.1365G>T p.T455= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV62116367; called by muse, mutect2, varscan2
- TRMT61B | c.444G>A p.E148= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV60257627; called by muse, mutect2, varscan2
- TRPM2 | c.2535G>A p.R845= | Silent (SNP) | VAF 89/233 reads (38%) | catalogued as rs777601205, COSV55966963; called by muse, mutect2, varscan2
- TRPS1 | c.3504C>T p.I1168= (on ENST00000220888 / NM_001330599.2; = p.I1181= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs1367896138, COSV55229758; called by muse, mutect2
- TRPS1 | c.1323C>T p.F441= (on ENST00000220888 / NM_001330599.2; = p.F454= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs375336150; called by muse, mutect2, varscan2
- TTF2 | c.2151C>T p.L717= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs757847842, COSV65632161, COSV65633164; called by muse, mutect2
- TTL | c.483C>G p.L161= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV51973481; called by muse, mutect2, varscan2
- TUBGCP3 | c.2142C>T p.F714= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56184817; called by muse, mutect2, varscan2
- UBE3C | c.717G>A p.E239= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV61951892; called by muse, mutect2, varscan2
- URAD | c.21C>T p.N7= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV60380945; called by muse, mutect2, varscan2
- USP11 | c.2517G>A p.E839= (on ENST00000218348; = p.E796= on NM_001371072.1) | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV99510976; called by muse, varscan2
- USP49 | c.501G>A p.A167= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs775973583, COSV51895290; called by muse, mutect2
- WDFY3 | c.5988G>A p.R1996= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV55695248; called by muse, mutect2, varscan2
- WDTC1 | c.552G>T p.L184= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as COSV60087458; called by muse, mutect2, varscan2
- YIF1B | c.318C>T p.I106= (on ENST00000339413 / NM_001039673.3; = p.I91= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as COSV56649812; called by muse, mutect2, varscan2
- ZAN | c.5121C>A p.A1707= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61806182; called by mutect2, varscan2
- ZFPL1 | c.684A>C p.G228= | Silent (SNP) | VAF 97/230 reads (42%) | catalogued as COSV51868757; called by muse, varscan2
- ZFYVE26 | c.3891C>G p.L1297= | Silent (SNP) | VAF 28/384 reads (7%) | catalogued as COSV61325344; called by muse, mutect2
- ZNF536 | c.402C>A p.L134= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100834789, COSV62820113; called by muse, mutect2, varscan2
- ZNF7 | c.1077G>A p.E359= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV57382848; called by muse, mutect2
- ZXDA | c.897C>A p.P299= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV62387604; called by muse, mutect2, varscan2
- CDKL1 | c.171+17523A>G | Intron (SNP) | VAF 24/87 reads (28%) | catalogued as rs867766833, COSV53578250; called by muse, mutect2, varscan2
- CDKN2A | c.150+89C>G | Intron (SNP) | VAF 37/373 reads (10%) | catalogued as COSV58686164; called by muse, mutect2, varscan2
- CHD3 | c.4358+174C>T | Intron (SNP) | VAF 11/81 reads (14%) | catalogued as rs766010552, COSV100391066; called by muse, mutect2, varscan2
- CSMD3 | c.178+59896C>A | Intron (SNP) | VAF 27/171 reads (16%) | catalogued as rs941693073, COSV52103828, COSV99820987; called by muse, mutect2, varscan2
- DST | c.4297-4203C>A | Intron (SNP) | VAF 29/220 reads (13%) | catalogued as COSV55030674, COSV99757055; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85415A>G | Intron (SNP) | VAF 29/48 reads (60%) | catalogued as COSV72275664; called by muse, mutect2, varscan2
- MASP1 | c.1303+5128C>A | Intron (SNP) | VAF 17/255 reads (7%) | catalogued as COSV99962401; called by muse, mutect2
- MIR129-1 | n.41T>C | RNA (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- MIR7-3 | n.105T>G | RNA (SNP) | VAF 35/152 reads (23%) | catalogued as rs1225518489; called by muse, mutect2, varscan2
- NOP56 | c.1010+145G>C | Intron (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100250159; called by muse, mutect2, varscan2
- PRR12 | c.52-555C>T | Intron (SNP) | VAF 9/37 reads (24%) | catalogued as rs1261956901, COSV69816770; called by muse, mutect2, varscan2
- SCP2D1 | c.-1G>A | 5'UTR (SNP) | VAF 13/107 reads (12%) | catalogued as COSV99602079; called by muse, varscan2
- SLCO1A2 | c.61-460G>T | Intron (SNP) | VAF 26/126 reads (21%) | catalogued as COSV100262032; called by muse, mutect2, varscan2
- SLCO1A2 | c.61-461G>T | Intron (SNP) | VAF 26/129 reads (20%) | catalogued as COSV100262034; called by muse, mutect2, varscan2
- SNORD116-13 | n.31C>A | RNA (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1009C>A | Intron (SNP) | VAF 27/195 reads (14%) | catalogued as COSV64749856; called by muse, mutect2, varscan2
- THSD4 | c.-80+15170G>A | Intron (SNP) | VAF 6/53 reads (11%) | catalogued as COSV62494182; called by muse, mutect2, varscan2
